Surgical pathology report (de-identified scan), TCGA case TCGA-MX-A5UG, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MSKCC, specimen TCGA-MX-A5UG-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

* Amended *

Patient: **[REDACTED]**
MRN: **[REDACTED]**
Account #: **[REDACTED]**
DOB: **[REDACTED]**
Physician: **[REDACTED]**
CC: **[REDACTED]**

Accession #: **[REDACTED]**
Service: **[REDACTED]**
Date of Procedure: **[REDACTED]**
Date of Receipt: **[REDACTED]**
Date of Amendment: **[REDACTED]**

....

Clinical Diagnosis & History:
T3N1 signet- ring cell gastric cancer distal stomach No neoadjuvant chemotherapy.

Specimens Submitted:

- 1: SP: Distal gastrectomy (fs)
- 2: SP: Proximal stomach (fs)
- 3: SP: Perigastric lymph nodes
- 4: SP: Biopsy left lobe of liver

AMENDED DIAGNOSIS:

- 1,2) STOMACH, DISTAL AND PROXIMAL; TOTAL GASTRECTOMY:
- INVASIVE ADENOCARCINOMA, SIGNET RING, LAUREN'S DIFFUSE TYPE, POORLY DIFFERENTIATED, OF LOWER THIRD (ANTRAL AREA/PYLORUS).
- THE TUMOR LENGTH IS 4.5 CM, THE WIDTH IS 4.0 CM, THE MAXIMAL THICKNESS IS 1.0 CM.
- THE TUMOR INVADES THE SUBSEROSEA AND IS PRESENT ON SEROSAL SURFACE (pT3).
- THE PATTERN OF INVASION IS INFILTRATIVE.
- VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- NO PERITONEAL TUMOR IMPLANTS ARE IDENTIFIED.
- BOTH DISTAL AND PROXIMAL MARGIN OF RESECTION ARE FREE OF CARCINOMA.
- THE NON-NEOPLASTIC STOMACH SHOWS CHRONIC GASTRITIS OF MODERATE DEGREE WITH INCOMPLETE INTESTINAL METAPLASIA.
- GASTROESOPHAGEAL JUNCTIONAL MUCOSA REVEALS BARRETT'S ESOPHAGUS WITHOUT DYSPLASIA.
- UNREMARKABLE OMENTUM.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): 2/14 (pN1).
- 3) "LYMPH NODE", PERIGASTRIC; BIOPSY:
- FIBROADIPOSE TISSUE, NO LYMPH NODES ARE IDENTIFIED.
- 4) LIVER, LEFT LOBE; BIOPSY:
- BENIGN HEPATIC PARENCHYMA WITH MILD PERIportal INFLAMMATION AND FIBROUS REACTIVE BILE DUCTULAR PROLIFERATION AND CHOLESTASIS.
- NO CARCINOMA SEEN.

** Continued on next page **

ICD0-3
path Adenocarcinoma, signet ring
cell type 8490/3
C44 Adenocarcinoma, diffuse type
8145/3
Site: Stomach, gastric
antrum C16.3
JW 3/18/13

[page 2 of 5]
Note:
This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:
Gross Description:

- 1). DM distal margin, shaved and submitted entirely

AMENDED REPORT:
Gross Description:

- 1). DM - distal stomach
DUM distal duodenal margin

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

- 1). The specimen is received fresh for frozen section consultation, labeled "distal gastrectomy freeze proximal margin". It consists of a distal portion of stomach with attached adipose tissue and omentum. The stomach measures 15 x 7 x 2.5 cm and has a pink-tan smooth serosal surface. The attached omentum measures 20 x 18 x 5 cm and is grossly unremarkable. The specimen is opened to reveal a firm, thickened, nodular area of mucosa measuring 4.5 x 4.0 x 1.0 cm. The tumor grossly involves the proximal margin and is 3.5 cm from the distal margin. Sectioning of the tumor reveals wall thickening up to 0.6 cm. The remaining gastric mucosa shows focal pinpoint ulcers. The specimen is submitted for lymph node dissection. Multiple lymph nodes are identified in the perigastric adipose tissue. All identified lymph nodes are submitted. Representative sections of the proximal margin are submitted for frozen section. The completion proximal gastrectomy is in part two. Portions of the tumor are submitted for TPS. Photographs are taken.

Summary of sections:

FSCA - frozen section control A
FSCB - frozen section control B
FSCC - frozen section control C
DM - distal stomach
T - tumor

** Continued on next page **

[page 3 of 5]
MU - mucosal ulcer
U - uninvolved gastric mucosa
LN - lymph nodes
O omentum
DUM distal duodenal margin

2). The specimen is received fresh for frozen section consultation, labeled "proximal stomach, freeze proximal margin". It consists of a proximal portion of stomach with attached adipose tissue and omentum. The stomach measures 7.2 cm in length by 10.3 cm in inner circumference cm and has a pink-tan smooth serosal surface. The attached omentum measures 27 x 12 x 1.7 cm and is grossly unremarkable. There is a 7.5 cm stapled line at the distal end. The small margin is opened. The specimen is opened to reveal no grossly identifiable residual tumor. The gastric mucosa shows prominent mucosal folds. There is an area of the mucosa adjacent to the stapled line that is flattened and somewhat granular. The serosa underneath the area is inked blue. The proximal margin is shaved and entirely submitted for frozen section diagnosis. The specimen is submitted for lymph node dissection. Multiple lymph nodes are identified in the perigastric adipose tissue. All identified lymph nodes are submitted.

Summary of sections:
FSCA and B - shaved proximal margin (entirely submitted)
MSL - representative sections from mucosa adjacent to stapled line
U - uninvolved gastric mucosa
O - omentum
LN - lymph nodes

3). The specimen is received in formalin, labeled "Peri-gastric lymph node" and consists of three pink tan fatty lymph node measuring 0.3 and 1.3 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
LN- lymph nodes

4). The specimen is received in formalin, labeled "Biopsy left lobe of liver" and consists of a 1.7 x 1.2 x 0.7 cm fragment of tan firm, liver tissue. The resected margin is inked in black the specimen is trisected and entirely submitted.

Summary of sections:
U - undesignated

[page 4 of 5]
Summary of Sections:

Part 1: SP: Distal gastrectomy (fs)

Block	Sect.	Site	PCs
1		ADD	1
6		dm	6
1		DUM	1
1		fsca	1
1		fscb	1
1		fscc	1
4		LN	12
1		mu	1
1		o	1
2		t	2
1		u	1

Part 2: SP: Proximal stomach (fs)

Block	Sect.	Site	PCs
1		fsca	1
1		fscb	1
1		ln	4
6		msl	6
3		o	3
2		u	2

Part 3: SP: Perigastric lymph nodes

Block	Sect.	Site	PCs
1		LN	3

Part 4: SP: Biopsy left lobe of liver

Block	Sect.	Site	PCs
1		U	3

Amendments

Original Diagnosis:

- 1,2) STOMACH, DISTAL AND PROXIMAL; TOTAL GASTRECTOMY:
- INVASIVE ADENOCARCINOMA, SIGNET RING, LAUREN'S DIFFUSE TYPE, POORLY DIFFERENTIATED, OF LOWER THIRD (ANTRAL AREA/PYLORUS).
- THE TUMOR LENGTH IS 4.5 CM, THE WIDTH IS 4.0 CM, THE MAXIMAL THICKNESS IS 1.0 CM.
- THE TUMOR INVADERS THE SUBSEROA AND IS PRESENT ON SEROSAL SURFACE (pT3).

** Continued on next page **

[page 5 of 5]
- THE PATTERN OF INVASION IS INFILTRATIVE.
- VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- NO PERITONEAL TUMOR IMPLANTS ARE IDENTIFIED.
- DISTAL MARGIN OF RESECTION IS DIFFUSELY INVOLVED BY MICROSCOPIC CARCINOMA.
- PROXIMAL MARGIN OF RESECTION IS FREE OF TUMOR.
- THE NON-NEOPLASTIC STOMACH SHOWS CHRONIC GASTRITIS OF MODERATE DEGREE WITH INCOMPLETE INTESTINAL METAPLASIA.
- GASTROESOPHAGEAL JUNCTIONAL MUCOSA REVEALS BARRETT'S ESOPHAGUS WITHOUT DYSPLASIA.
- UNREMARKABLE OMENTUM.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): 2/13 (pN1).
- 3) "LYMPH NODE", PERIGASTRIC; BIOPSY:
- FIBROADIPOSE TISSUE, NO LYMPH NODES ARE IDENTIFIED.
- 4) LIVER, LEFT LOBE; BIOPSY:
- BENIGN HEPATIC PARENCHYMA WITH MILD PERIportal INFLAMMATION AND FIBROUS REACTIVE BILE DUCTULAR PROLIFERATION AND CHOLESTASIS.
- NO CARCINOMA SEEN.

Intraoperative Consultation:

NOTE: THE DIAGNOSES GIVEN IN THIS SECTION PERTAIN ONLY TO THE TISSUE SAMPLE EXAMINED AT THE TIME OF THE INTRAOPERATIVE CONSULTATION.

- 1) FROZEN SECTION DIAGNOSIS: DISTAL GASTRECTOMY. PROXIMAL MARGIN POSITIVE FOR CARCINOMA.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: PROXIMAL STOMACH. PROXIMAL LMARGIN NEGATIVE.
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Reviewed Initials	Date Reviewed: 5/4/13	

Source: NCI Genomic Data Commons file 6dbad52c-786d-4885-aeee-5f995452e0fa (TCGA-MX-A5UG.141CEB44-5BA7-4FB3-87CD-47CE07056889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).